Somatic mutation profile of tumor specimen TCGA-KO-8404-01A (aliquot TCGA-KO-8404-01A-11D-2310-10) from TCGA case TCGA-KO-8404, project TCGA-KICH (Kidney Chromophobe). Sex at birth: male; Vital status: Dead; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 78.6 years (28,705 days).
Specimen TCGA-KO-8404-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6ca2820d-357a-4df8-aecb-5267dd3a47ca.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KO-8404-11A (Solid Tissue Normal), aliquot TCGA-KO-8404-11A-01D-2311-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1f81742f-22a7-4aac-895c-12492b9746c0

The open-access MAF lists 44 somatic variants for this specimen: 35 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 8, Nonsense Mutation 3, Frame Shift Del 3, Frame Shift Ins 2, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.673-1G>A p.X225_splice | Splice Site (SNP) | VAF 93/126 reads (74%) | hotspot (GDC flag); catalogued as rs878854073, CS011061, COSV52662773, COSV52705331, COSV52707963, COSV53154363; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACSM2A | c.1724G>A p.R575H (on ENST00000219054; = p.R496H on NM_001308169.2) | Missense Mutation (SNP) | VAF 59/165 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs1173954214, COSV54591581; called by muse, mutect2, varscan2
- ADAMTSL1 | c.1669C>T p.Q557* | Nonsense Mutation (SNP) | VAF 8/126 reads (6%) | catalogued as COSV99444923; called by muse, mutect2
- ARHGAP29 | c.3488G>A p.W1163* | Nonsense Mutation (SNP) | VAF 72/220 reads (33%) | catalogued as COSV99559062; called by muse, mutect2, varscan2
- C11orf80 | c.441_442insA p.S148Ifs*15 | Frame Shift Ins (INS) | VAF 101/466 reads (22%) | catalogued as COSV100691146; called by mutect2, pindel, varscan2
- CCSER1 | c.140C>T p.S47F | Missense Mutation (SNP) | VAF 21/195 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100396277; called by muse, mutect2, varscan2
- CSMD1 | c.8388C>A p.N2796K (on ENST00000520002; = p.N2795K on NM_033225.6) | Missense Mutation (SNP) | VAF 52/80 reads (65%) | SIFT deleterious (0.04); PolyPhen benign (0.182); catalogued as COSV100153869; called by muse, mutect2, varscan2
- DFFA | c.412A>G p.I138V | Missense Mutation (SNP) | VAF 124/187 reads (66%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.726); catalogued as COSV100986702; called by muse, mutect2, varscan2
- FAM162A | c.227G>A p.R76H | Missense Mutation (SNP) | VAF 66/219 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.146); catalogued as rs149572114, COSV99216497; called by muse, mutect2, varscan2
- FAM83C | c.2156G>A p.R719Q | Missense Mutation (SNP) | VAF 99/190 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.852); catalogued as rs747968163, COSV100981716; called by muse, mutect2, varscan2
- GLDC | c.2674G>A p.A892T | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs146939116; called by muse, mutect2, varscan2
- GLRA1 | c.1310T>G p.I437S (on ENST00000455880 / NM_001146040.2; = p.I429S on NM_000171.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/200 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV99199690; called by muse, mutect2, varscan2
- HUWE1 | c.7768C>A p.L2590I | Missense Mutation (SNP) | VAF 60/88 reads (68%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.931); catalogued as COSV99474282; called by muse, varscan2
- IZUMO2 | c.344C>T p.A115V | Missense Mutation (SNP) | VAF 77/188 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.149); catalogued as rs751425386, COSV53229157, COSV99518388; called by muse, mutect2, varscan2
- KLHDC2 | c.416G>A p.G139E | Missense Mutation (SNP) | VAF 48/143 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100027140; called by muse, mutect2, varscan2
- KRT3 | c.52G>A p.G18S | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.074); catalogued as rs750889026, COSV58815262; called by muse, mutect2, varscan2
- LMTK3 | c.2887G>T p.E963* | Nonsense Mutation (SNP) | VAF 33/80 reads (41%) | catalogued as COSV99541238; called by muse, mutect2, varscan2
- LRPPRC | c.3171T>A p.N1057K | Missense Mutation (SNP) | VAF 200/290 reads (69%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs765647846, COSV99581497; called by muse, mutect2, varscan2
- OR51M1 | c.152T>A p.I51N | Missense Mutation (SNP) | VAF 62/233 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV100150385; called by muse, mutect2, varscan2
- OR56A1 | c.595A>G p.R199G | Missense Mutation (SNP) | VAF 53/81 reads (65%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.579); catalogued as COSV57364314; called by muse, mutect2, varscan2
- PPP1CC | c.560G>A p.R187Q | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.024); catalogued as rs1276219223, COSV100534983; called by muse, mutect2, varscan2
- PRKAG3 | c.218G>T p.G73V | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.397); catalogued as rs1013713457, COSV99292137; called by muse, mutect2
- RPL18A | c.115G>A p.V39I | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.079); catalogued as rs779503423, COSV99714509; called by muse, mutect2, varscan2
- SCNN1D | c.1091G>A p.G364E (on ENST00000338555; = p.G528E on NM_001130413.4) | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100330282; called by muse, mutect2, varscan2
- SGIP1 | c.1334G>A p.R445Q | Missense Mutation (SNP) | VAF 50/163 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs542858072; called by muse, mutect2, varscan2
- SYNGAP1 | c.872A>C p.Y291S | Missense Mutation (SNP) | VAF 42/77 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99539025; called by muse, mutect2, varscan2
- TTC29 | c.790G>A p.A264T | Missense Mutation (SNP) | VAF 11/248 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV57274196; called by muse, mutect2
- UBE3C | c.2518G>T p.A840S | Missense Mutation (SNP) | VAF 57/137 reads (42%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.687); catalogued as COSV100780095; called by muse, mutect2, varscan2
- UBE3C | c.2519C>T p.A840V | Missense Mutation (SNP) | VAF 58/138 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100780096; called by muse, mutect2, varscan2
- UQCRFS1 | c.588G>C p.R196S | Missense Mutation (SNP) | VAF 85/328 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100508183; called by muse, mutect2, varscan2
- WWTR1 | c.820C>T p.P274S | Missense Mutation (SNP) | VAF 100/146 reads (68%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100640969; called by muse, varscan2
- KDELR3 | c.439del p.I147* | Frame Shift Del (DEL) | VAF 111/352 reads (32%) | called by mutect2, pindel, varscan2
- KLB | c.2274_2278del p.W758Cfs*70 | Frame Shift Del (DEL) | VAF 7/38 reads (18%) | called by mutect2, pindel, varscan2
- MLYCD | c.668dup p.N223Kfs*38 | Frame Shift Ins (INS) | VAF 51/98 reads (52%) | called by mutect2, pindel, varscan2
- RB1 | c.2336_2345del p.L779Yfs*28 | Frame Shift Del (DEL) | VAF 47/82 reads (57%) | called by mutect2, pindel, varscan2
- ADCY9 | c.2628C>T p.P876= | Silent (SNP) | VAF 34/87 reads (39%) | catalogued as rs750255189, COSV53575312; called by muse, mutect2, varscan2
- CTCFL | c.1437T>C p.T479= | Silent (SNP) | VAF 60/290 reads (21%) | catalogued as COSV99713322; called by muse, mutect2, varscan2
- DNM3 | c.1368G>A p.T456= | Silent (SNP) | VAF 25/70 reads (36%) | catalogued as rs771664927, COSV62452474; called by muse, mutect2, varscan2
- LRRC25 | c.600G>A p.E200= | Silent (SNP) | VAF 35/97 reads (36%) | catalogued as rs747659251, COSV100170623; called by muse, mutect2, varscan2
- NAB2 | c.549G>T p.R183= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV100272805, COSV55665489; called by muse, mutect2, varscan2
- SDK2 | c.4824G>T p.G1608= | Silent (SNP) | VAF 55/77 reads (71%) | catalogued as COSV101168668; called by muse, mutect2, varscan2
- SLC15A2 | c.2187C>A p.L729= | Silent (SNP) | VAF 72/251 reads (29%) | catalogued as COSV99815870; called by muse, mutect2, varscan2
- ZBED9 | c.1551T>A p.T517= | Silent (SNP) | VAF 44/194 reads (23%) | catalogued as COSV101509399, COSV101509446; called by muse, mutect2, varscan2
- C12orf77 | n.623G>A | RNA (SNP) | VAF 8/55 reads (15%) | called by muse, mutect2, varscan2
